Somatic mutation profile of tumor specimen TCGA-KK-A6E3-01A (aliquot TCGA-KK-A6E3-01A-21D-A30E-08) from TCGA case TCGA-KK-A6E3, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.3 years (20,547 days).
Specimen TCGA-KK-A6E3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 392bff85-3058-4228-a939-0f729b9c7fd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A6E3-11A (Solid Tissue Normal), aliquot TCGA-KK-A6E3-11A-11D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ae9171a-18e6-4e1a-98bf-fd31caa4dba5

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Frame Shift Del 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.3092C>T p.A1031V | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs1335954608, COSV62322852; called by muse, mutect2
- ADIPOR2 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as COSV63946204; called by muse, mutect2
- CDH24 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs955239180, COSV52975829; called by muse, mutect2
- CRACD | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51720188; called by muse, mutect2, varscan2
- DMPK | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.629); catalogued as COSV52177742; called by muse, mutect2
- GASK1B | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV56706916; called by muse, mutect2
- GNRHR | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs150422225; called by muse, mutect2, varscan2
- H3C8 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV59952974; called by muse, mutect2
- IL17RA | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs762369642, COSV60052947; called by mutect2, varscan2
- ITGB8 | c.1754G>A p.C585Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56007834, COSV56007992; called by muse, mutect2
- KMT2D | c.16278C>G p.Y5426* | Nonsense Mutation (SNP) | VAF 58/310 reads (19%) | catalogued as COSV56435722; called by muse, mutect2, varscan2
- LRP1B | c.4853A>T p.E1618V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV67214047; called by muse, mutect2
- MCPH1 | c.1875C>G p.D625E | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60913051; called by muse, mutect2
- MYL6B | c.488G>C p.G163A | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV52878675; called by muse, mutect2
- PAN2 | c.3583G>A p.V1195I (on ENST00000425394 / NM_001127460.3; = p.V1191I on NM_014871.5) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.096); catalogued as rs1361484607, COSV56264302; called by muse, mutect2
- PLSCR5 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV71649027; called by muse, mutect2, varscan2
- POLQ | c.6494T>A p.I2165N | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV51750873; called by muse, mutect2
- POLQ | c.5423T>C p.L1808S | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV51750886; called by muse, mutect2
- PYGL | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as rs760187622, COSV53585666; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGCZ | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.058); catalogued as rs1188331361, COSV66003298, COSV66013811; called by muse, mutect2
- ZNF519 | c.1010A>G p.Q337R | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.028); catalogued as COSV73913330; called by muse, mutect2
- ZNF883 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs376605473; called by muse, mutect2, varscan2
- MEST | c.845del p.P282Hfs*5 | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | called by mutect2, pindel, varscan2
- TMPRSS2 | c.1017dup p.K340Qfs*6 | Frame Shift Ins (INS) | VAF 13/142 reads (9%) | called by mutect2, pindel
- CSPG4 | c.99C>T p.F33= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1234757339, COSV57894502; called by muse, mutect2, varscan2
- FMNL3 | c.2805C>A p.R935= | Silent (SNP) | VAF 10/145 reads (7%) | catalogued as rs1277685547, COSV53301371; called by muse, mutect2
- MPEG1 | c.562A>C p.R188= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV57090326; called by muse, mutect2
- PROSER1 | c.2622G>A p.P874= | Silent (SNP) | VAF 20/348 reads (6%) | catalogued as rs370484502, COSV61486879; called by muse, mutect2
- RAB13 | c.57G>A p.V19= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1052206921, COSV63933714; called by muse, mutect2, varscan2
